FM case AD10318 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Bladder.
https://portal.gdc.cancer.gov/cases/211cfc35-c475-457b-a307-f930719892dc

Male, 67.8 years: Carcinoma, NOS (ICD-O-3 8010/3) of the bladder; metastasis biopsied or resected from the lymph node. Tumor nuclei on the sequenced sample's slide: 50% (pathologist estimate recorded by GDC). Sample type: Metastatic.
